Somatic mutation profile of tumor specimen C3N-00328-05 (aliquot CPT0019840009) from CPTAC case C3N-00328, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 62.4 years (22,800 days).
Specimen C3N-00328-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca20c666-024a-4b63-8269-4dbbdee2c1fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00328-31 (Blood Derived Normal), aliquot CPT0020410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/569232cc-28ae-4672-b958-fccd4e5911da

The open-access MAF lists 7,332 somatic variants for this specimen: 5,361 protein-altering or splice-affecting, 1,078 silent, 893 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,448, Silent 1,078, Nonsense Mutation 770, Intron 447, 3'UTR 154, RNA 146, 5'UTR 72, Splice Region 59, Splice Site 55, 3'Flank 38, 5'Flank 35, Frame Shift Ins 14.

Variants (750 of 7,332; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADA | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 71/371 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs121908722, CM109816, CM930009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGL | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 38/230 reads (17%) | catalogued as rs766536350, CM0910189; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APC | c.2828C>A p.S943* | Nonsense Mutation (SNP) | VAF 28/167 reads (17%) | catalogued as rs1554084512, CM021064, CM086470, COSV57334177, COSV57340756, COSV57390748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4634C>A p.S1545* | Nonsense Mutation (SNP) | VAF 47/207 reads (23%) | catalogued as rs863225356, CM023012, COSV57326602, COSV57339509, COSV57340522; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.9730C>T p.R3244* | Nonsense Mutation (SNP) | VAF 43/142 reads (30%) | catalogued as rs199422195, CM077231, COSV54130194; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 30/170 reads (18%) | catalogued as rs876660933, COSV53735564, COSV53743058; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- BBS2 | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 66/385 reads (17%) | catalogued as rs567573386, CM114528, COSV55325564; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCKDHB | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 90/510 reads (18%) | catalogued as rs1057516799, CM062457, COSV100243380; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRWD3 | c.3718C>T p.R1240* | Nonsense Mutation (SNP) | VAF 31/226 reads (14%) | catalogued as rs878853055, COSV64743451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CAPN3 | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 95/478 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780290, CM970224, COSV55522473; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CLCN1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 111/653 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912805, CM1313399, CM950266, COSV58367720; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL5A1 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 42/279 reads (15%) | catalogued as rs1554787811; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EDARADD | c.454G>A p.E152K (on ENST00000334232 / NM_145861.4; = p.E142K on NM_080738.4) | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs74315309, CM013622, COSV100512683; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.2645C>T p.A882V | Missense Mutation (SNP) | VAF 95/506 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs794728195, CM042039, COSV57322094; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 17/114 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, varscan2
- FUBP1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 18/115 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408536007, COSV53927182; called by muse, mutect2, varscan2
- GNE | c.479G>A p.R160Q (on ENST00000396594 / NM_001128227.3; = p.R129Q on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/370 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.932); catalogued as rs748704459, CM042357, COSV64951970; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GNPTAB | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 48/155 reads (31%) | catalogued as rs281864982, CM100341, COSV54779098, COSV68449787; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNS | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 59/349 reads (17%) | catalogued as rs119461974, CM030467, COSV50697172; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GTF3C1 | c.4096G>A p.E1366K | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as rs1060499746, CM1512500, COSV62239401; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- INVS | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | catalogued as rs267607185, CM032003, COSV52449170; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 55/309 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LHCGR | c.1847C>A p.S616Y | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912525, CM960941, COSV54297137; ClinVar: pathogenic; called by muse, varscan2
- LHCGR | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 61/296 reads (21%) | catalogued as rs121912524, CM960940, COSV54292419; ClinVar: pathogenic; called by muse, varscan2
- MAGT1 | c.313C>T p.R105* (on ENST00000618282 / NM_001367916.1; = p.R137* on NM_032121.5) | Nonsense Mutation (SNP) | VAF 54/300 reads (18%) | catalogued as rs387906724, CM116461, COSV63781525; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MFN2 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 80/580 reads (14%) | catalogued as rs1057517987, CM050074, COSV52422272; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MSTO1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749922789, COSV55471710; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.1490C>A p.S497Y | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587783800, COSV60333561; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.5044C>T p.R1682* | Nonsense Mutation (SNP) | VAF 19/162 reads (12%) | catalogued as rs797045769, COSV56944290; ClinVar: pathogenic; called by muse, varscan2
- NSD1 | c.6049C>T p.R2017W | Missense Mutation (SNP) | VAF 132/409 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587784176, CM031305, COSV100728999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- P3H1 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 65/385 reads (17%) | catalogued as rs140468248, COSV99355190; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH12 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 32/161 reads (20%) | catalogued as rs370283860; ClinVar: pathogenic; called by muse, varscan2
- PGAP1 | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as rs1169608420; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 17/129 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519929, CM126687, COSV55873676, COSV55913749; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PKHD1 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 73/451 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770494581, CM149111, COSV61864021; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 40/317 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- POLG | c.2870C>T p.A957V | Missense Mutation (SNP) | VAF 79/493 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753160398, CM117640; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 40/255 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1111457, COSV64291669, COSV64295080, COSV64295612; called by muse, mutect2, varscan2
- RIPPLY2 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 16/114 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100859440, COSV63746041; called by muse, mutect2, varscan2
- RLIM | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1569309460, COSV60325321; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs397516539, CM065450, CM156349, COSV63686290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 22/140 reads (16%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.99490C>T p.R33164* (on ENST00000591111; = p.R25740* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 52/239 reads (22%) | catalogued as rs750519430, COSV60279899; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TUBA1A | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 64/395 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.019); catalogued as rs1057517858, CM103939, COSV55496874, COSV55497525; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TUBA1A | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 85/482 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs886039513, CM145649, COSV55497204; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZHX3 | c.747C>A p.N249K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs201454849, CM121425, COSV58380689; called by muse, mutect2, varscan2
- A2M | c.4167C>A p.F1389L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59384269; called by muse, varscan2
- A2ML1 | c.2519C>A p.S840Y | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs960169988, COSV55286694; called by muse, mutect2, varscan2
- A4GNT | c.962G>A p.R321K | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759650530, COSV52629796; called by muse, mutect2, varscan2
- AADAT | c.739C>A p.L247I | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV100528530; called by muse, mutect2, varscan2
- AASS | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 123/675 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.029); catalogued as rs867630104; called by muse, mutect2, varscan2
- AATF | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 19/193 reads (10%) | catalogued as rs374671217; called by muse, mutect2, varscan2
- ABCA1 | c.6772G>T p.E2258* | Nonsense Mutation (SNP) | VAF 29/186 reads (16%) | catalogued as COSV101037015; called by muse, mutect2, varscan2
- ABCA12 | c.7473G>T p.K2491N (on ENST00000272895 / NM_173076.3; = p.K2173N on NM_015657.3) | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as COSV99791735; called by muse, mutect2, varscan2
- ABCA12 | c.3679G>A p.E1227K (on ENST00000272895 / NM_173076.3; = p.E909K on NM_015657.3) | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286289900; called by muse, mutect2, varscan2
- ABCA12 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 38/209 reads (18%) | catalogued as COSV55966580; called by muse, mutect2, varscan2
- ABCA13 | c.10007A>G p.Y3336C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs924321070; called by muse, varscan2
- ABCA13 | c.11393G>T p.S3798I | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV101447199; called by muse, mutect2, varscan2
- ABCA13 | c.14539G>A p.E4847K | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs267601532, COSV68943207; called by muse, mutect2, varscan2
- ABCA6 | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as rs747530521; called by muse, mutect2, varscan2
- ABCA6 | c.2755G>T p.D919Y | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99447571; called by muse, mutect2
- ABCA6 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV52641630; called by muse, mutect2
- ABCB1 | c.857G>T p.R286I | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.762); catalogued as COSV55944621, COSV55950626; called by muse, mutect2, varscan2
- ABCB7 | c.1774C>A p.L592I (on ENST00000373394 / NM_001271696.3; = p.L593I on NM_004299.6) | Missense Mutation (SNP) | VAF 49/256 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV53719092; called by muse, mutect2, varscan2
- ABCC11 | c.2770G>A p.A924T | Missense Mutation (SNP) | VAF 48/360 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs138453043; called by muse, mutect2, varscan2
- ABCC5 | c.1149A>C p.K383N | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV99656684; called by muse, mutect2
- ABCC6 | c.3105C>A p.F1035L | Missense Mutation (SNP) | VAF 63/548 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52742009, COSV99229129; called by muse, mutect2, varscan2
- ABCD3 | c.614C>A p.S205* | Nonsense Mutation (SNP) | VAF 38/185 reads (21%) | catalogued as COSV100238765; called by muse, mutect2, varscan2
- ABCD3 | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 54/362 reads (15%) | catalogued as rs1557691806, COSV64642599; called by muse, mutect2, varscan2
- ABHD6 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 36/271 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.439); catalogued as COSV99917008; called by muse, mutect2, varscan2
- ABI3BP | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs759720414, COSV52530661; called by mutect2, varscan2
- ABL2 | c.982G>T p.E328* (on ENST00000502732 / NM_007314.4; = p.E313* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 40/153 reads (26%) | catalogued as COSV100772713; called by muse, mutect2, varscan2
- AC011462.1 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as rs775190884, COSV60531386; called by muse, mutect2, varscan2
- AC069544.2 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV65683908; called by muse, mutect2
- AC104389.6 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 68/472 reads (14%) | catalogued as rs33963857, COSV100400543, COSV57963060; called by muse, mutect2, varscan2
- ACAD10 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766583324, COSV58155640; called by muse, mutect2, varscan2
- ACAD9 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs199504238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACBD3 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 58/418 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs374978330; called by muse, mutect2, varscan2
- ACE | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 75/404 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs753078890, COSV52017529; called by muse, varscan2
- ACHE | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs374462106; called by mutect2, varscan2
- ACOT12 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 22/138 reads (16%) | catalogued as rs780095623, COSV56892749; called by muse, mutect2, varscan2
- ACSL4 | c.2107G>T p.D703Y (on ENST00000340800 / NM_022977.2; = p.D662Y on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV61615594; called by muse, mutect2, varscan2
- ACSM3 | c.1087A>C p.K363Q | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99184004; called by muse, mutect2, varscan2
- ACSM4 | c.1590G>T p.E530D | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs1412358684, COSV68067591, COSV68067628; called by muse, mutect2, varscan2
- ACSS3 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778280883, COSV54083909; called by muse, mutect2, varscan2
- ACTBL2 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.81); catalogued as rs373420374, COSV70661090; called by muse, mutect2, varscan2
- ACTL8 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs373308699; called by muse, mutect2, varscan2
- ACTN2 | c.1517G>T p.R506I | Missense Mutation (SNP) | VAF 66/419 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV63974570; called by muse, mutect2, varscan2
- ACTR3 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 18/134 reads (13%) | catalogued as COSV54302653; called by muse, mutect2, varscan2
- ACTR3C | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); catalogued as rs780988364; called by muse, mutect2, varscan2
- ACVR2B | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 84/411 reads (20%) | catalogued as COSV61702334; called by muse, mutect2, varscan2
- ADAM23 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs746564560; called by muse, mutect2, varscan2
- ADAM29 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV63669214; called by muse, mutect2, varscan2
- ADAM32 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs567675296, COSV65946823; called by muse, mutect2, varscan2
- ADAM32 | c.1580G>T p.R527I | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV65953272; called by muse, mutect2, varscan2
- ADAMTS1 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 44/199 reads (22%) | catalogued as rs944862656, COSV53169549; called by muse, mutect2, varscan2
- ADAMTS12 | c.287C>A p.S96Y | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.222); catalogued as COSV100711630; called by muse, mutect2, varscan2
- ADAMTS20 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 21/113 reads (19%) | catalogued as rs749434282, COSV67129549; called by muse, mutect2, varscan2
- ADAMTS3 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV99711788; called by muse, mutect2, varscan2
- ADAMTSL3 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54443016, COSV99720411; called by muse, mutect2
- ADCY8 | c.3242C>A p.S1081* | Nonsense Mutation (SNP) | VAF 12/154 reads (8%) | catalogued as COSV53915281; called by muse, mutect2
- ADCY9 | c.2319G>T p.K773N | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV53578585; called by muse, mutect2, varscan2
- ADGRA1 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs377602892; called by muse, mutect2, varscan2
- ADGRB3 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs922398016, COSV65388803; called by muse, varscan2
- ADGRB3 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV65387066; called by muse, varscan2
- ADGRD1 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs951477753; called by muse, mutect2, varscan2
- ADGRE5 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs750288090, COSV99662851; called by muse, mutect2, varscan2
- ADGRG2 | c.352G>T p.D118Y (on ENST00000379869 / NM_001079858.3; = p.D115Y on NM_005756.4) | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV61339964; called by muse, varscan2
- ADGRG2 | c.256G>A p.E86K (on ENST00000379869 / NM_001079858.3; = p.E83K on NM_005756.4) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756209879; called by mutect2, varscan2
- ADGRL1 | c.1132G>A p.D378N (on ENST00000340736 / NM_001008701.3; = p.D373N on NM_014921.5) | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364595862; called by muse, mutect2, varscan2
- ADGRL3 | c.4399G>T p.E1467* (on ENST00000506720 / NM_001322402.2; = p.E1356* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 49/273 reads (18%) | catalogued as COSV99072520; called by muse, mutect2, varscan2
- ADGRV1 | c.2374G>T p.E792* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV67983717; called by muse, mutect2
- ADGRV1 | c.9680G>A p.R3227Q | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs371542701, COSV101316731; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.14404C>T p.R4802* | Nonsense Mutation (SNP) | VAF 25/250 reads (10%) | catalogued as rs1236715896, CM0911268, COSV67978996; called by muse, mutect2, varscan2
- ADGRV1 | c.15106G>A p.D5036N | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs867504287, COSV67991999; called by muse, mutect2, varscan2
- ADGRV1 | c.15673T>C p.S5225P | Missense Mutation (SNP) | VAF 52/390 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs751862277; called by muse, varscan2
- ADH1B | c.1062A>C p.E354D | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV59297586; called by muse, mutect2, varscan2
- ADNP | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.208); catalogued as COSV62424683; called by muse, mutect2
- ADSS1 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs145306973; called by muse, mutect2, varscan2
- AFAP1L2 | c.312G>T p.K104N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.456); catalogued as rs1378258181; called by muse, mutect2
- AFF1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 14/140 reads (10%) | catalogued as rs753451653, COSV100321078; called by mutect2, varscan2
- AFF2 | c.3819C>A p.F1273L | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53989173; called by muse, mutect2
- AFM | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV56919366; called by muse, mutect2
- AGAP2 | c.1329G>T p.K443N (on ENST00000547588 / NM_001122772.2; = p.K107N on NM_014770.4) | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57730089; called by muse, mutect2, varscan2
- AGBL1 | c.128G>T p.R43I | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756979963, COSV69794552, COSV69795260; called by muse, mutect2, varscan2
- AGBL2 | c.1654C>A p.L552M | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV54090837; called by muse, mutect2, varscan2
- AGBL3 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 19/144 reads (13%) | catalogued as COSV99310427; called by muse, mutect2, varscan2
- AGBL3 | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99311100; called by muse, mutect2, varscan2
- AGR2 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 61/267 reads (23%) | catalogued as COSV68596348; called by muse, mutect2, varscan2
- AGTPBP1 | c.1553G>T p.R518I (on ENST00000357081 / NM_001330701.2; = p.R478I on NM_015239.2) | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV61268456; called by muse, mutect2, varscan2
- AHCYL2 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs201615414, COSV61487208; called by muse, mutect2, varscan2
- AICDA | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs373061990, COSV57563722, COSV57563879; called by muse, mutect2, varscan2
- AIFM1 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 86/411 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs747871895, COSV54852707; called by muse, mutect2, varscan2
- AK5 | c.312C>A p.F104L (on ENST00000354567 / NM_174858.3; = p.F78L on NM_012093.4) | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.754); catalogued as COSV58355241; called by muse, mutect2, varscan2
- AKAP13 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs779495573, COSV100773513; called by muse, mutect2, varscan2
- AKAP7 | c.172A>C p.N58H | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.671); catalogued as COSV63505400; called by muse, mutect2
- AKAP9 | c.9994C>T p.R3332* (on ENST00000359028; = p.R3308* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 68/391 reads (17%) | catalogued as rs771217988, COSV62341755; called by muse, mutect2, varscan2
- AKT3 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV55612635; called by muse, varscan2
- AL592490.1 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as rs748943494, COSV69426364; called by mutect2, varscan2
- AL662899.2 | c.63C>A p.F21L | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.314); catalogued as COSV100788992; called by muse, varscan2
- ALAS2 | c.185C>A p.S62Y | Missense Mutation (SNP) | VAF 49/345 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV58192341; called by muse, mutect2, varscan2
- ALDH1A2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs376965202; called by muse, mutect2, varscan2
- ALDH1A2 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as rs201593015; called by muse, mutect2, varscan2
- ALDH1L2 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 48/401 reads (12%) | catalogued as COSV51554593; called by muse, mutect2, varscan2
- ALDH9A1 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.821); catalogued as rs767836676, COSV100699278, COSV61340553; called by muse, mutect2, varscan2
- ALG1 | c.245G>T p.R82I | Missense Mutation (SNP) | VAF 70/622 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV99275664; called by mutect2, varscan2
- ALG10B | c.709C>A p.L237I | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.068); catalogued as COSV100439884; called by muse, mutect2, varscan2
- ALG11 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146283420; called by muse, mutect2, varscan2
- ALG6 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 49/324 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746339839, COSV54765958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG8 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 36/308 reads (12%) | catalogued as rs533704173, COSV55202191, COSV55202506; called by muse, mutect2, varscan2
- ALKBH8 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV52833242; called by muse, mutect2
- ALOX12 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs200546604; called by muse, mutect2, varscan2
- ALPP | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs753056192, COSV67395812; called by muse, mutect2, varscan2
- ALS2 | c.4262G>A p.R1421Q | Missense Mutation (SNP) | VAF 59/422 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.895); catalogued as rs770885030, COSV51888325, COSV51889832; called by muse, mutect2, varscan2
- ALX3 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 72/432 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746228217, COSV100873871; called by muse, mutect2, varscan2
- AMPD1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 56/373 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs149424604, COSV100814939; called by muse, mutect2, varscan2
- ANK1 | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 67/577 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV55900402; called by muse, mutect2, varscan2
- ANK2 | c.7084A>G p.K2362E | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs760096507; called by muse, mutect2, varscan2
- ANK3 | c.5237C>A p.S1746Y | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.204); catalogued as rs754173928, COSV55071553, COSV55072795; called by muse, mutect2, varscan2
- ANK3 | c.3526C>T p.R1176* (on ENST00000280772 / NM_001320874.2; = p.R310* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 32/193 reads (17%) | catalogued as rs142673853, COSV55052053; called by muse, mutect2, varscan2
- ANKFN1 | c.2733G>T p.E911D (on ENST00000653862; = p.E764D on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as rs1463947426; called by muse, mutect2
- ANKRD11 | c.2167G>T p.D723Y | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56371297; called by muse, mutect2, varscan2
- ANKRD12 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as rs1365330076; called by muse, mutect2, varscan2
- ANKRD12 | c.3922C>T p.R1308* | Nonsense Mutation (SNP) | VAF 27/147 reads (18%) | catalogued as rs766734820, COSV50819104; called by muse, mutect2, varscan2
- ANKRD13C | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV52028752; called by muse, varscan2
- ANKRD18B | c.1802G>T p.R601I | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV52085286; called by muse, mutect2
- ANKRD26 | c.4278G>T p.K1426N | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs552031641, COSV65779346; called by mutect2, varscan2
- ANKRD26 | c.3184C>A p.L1062I | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs763827709, COSV65778223; called by muse, mutect2, varscan2
- ANKRD30A | c.450G>T p.E150D (on ENST00000611781; = p.E94D on NM_052997.2) | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV64606510; called by muse, mutect2, varscan2
- ANKRD30A | c.2482G>T p.E828* (on ENST00000611781; = p.E772* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV64605164; called by mutect2, varscan2
- ANKRD30A | c.2839G>T p.E947* (on ENST00000611781; = p.E891* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as rs371663598, COSV64603807; called by muse, varscan2
- ANKRD36C | c.3017C>T p.S1006L | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as rs777312362; called by muse, mutect2, varscan2
- ANKRD36C | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV54766351; called by muse, varscan2
- ANKRD62 | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.403); catalogued as COSV100019428; called by muse, mutect2, varscan2
- ANKS1B | c.1006A>C p.K336Q | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); catalogued as COSV61338929; called by muse, mutect2, varscan2
- ANKS6 | c.1598A>G p.D533G | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs781718987; called by muse, mutect2, varscan2
- ANKS6 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762633578, COSV62049898; called by mutect2, varscan2
- ANKUB1 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs996147548, COSV67167604; called by muse, mutect2, varscan2
- ANO10 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 36/236 reads (15%) | catalogued as COSV52730752, COSV52733131; called by muse, mutect2, varscan2
- ANO2 | c.606A>C p.K202N (on ENST00000356134 / NM_001278597.3; = p.K206N on NM_001278596.3) | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59015586; called by muse, mutect2, varscan2
- ANO3 | c.1367A>G p.D456G | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as rs777629771; called by muse, mutect2, varscan2
- ANO4 | c.419G>T p.R140I (on ENST00000392977 / NM_001286615.2; = p.R105I on NM_178826.4) | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.584); catalogued as rs1442864160, COSV54592395; called by muse, mutect2, varscan2
- ANO4 | c.809G>T p.R270I (on ENST00000392977 / NM_001286615.2; = p.R235I on NM_178826.4) | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1245505933; called by muse, mutect2, varscan2
- ANO4 | c.2131G>A p.D711N (on ENST00000392977 / NM_001286615.2; = p.D676N on NM_178826.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.879); catalogued as rs754705690, COSV54588684, COSV54592568; called by mutect2, varscan2
- ANOS1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 31/556 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs1404298787, COSV52916162; called by muse, mutect2
- AP1S1 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs753811377; called by mutect2, varscan2
- AP3B1 | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 69/361 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748191084, COSV54877031; called by muse, mutect2, varscan2
- AP3B1 | c.1398G>T p.K466N | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54886035; called by muse, mutect2, varscan2
- AP4E1 | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs144189610, COSV55915364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APBB1 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 52/360 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1190353452, COSV54973465; called by muse, mutect2, varscan2
- APC2 | c.3370G>A p.V1124I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1370175250, COSV99279084; called by muse, mutect2, varscan2
- APEH | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs779678983, COSV56531982; called by muse, mutect2, varscan2
- APH1A | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.142); catalogued as rs368536742, COSV52530067; called by muse, mutect2, varscan2
- APOB | c.9107C>A p.S3036Y | Missense Mutation (SNP) | VAF 59/276 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV51925687; called by muse, mutect2, varscan2
- APOB | c.3974C>A p.S1325Y | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV51940116; called by muse, mutect2, varscan2
- APOL5 | c.780G>T p.K260N | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV50766491, COSV50768685; called by muse, mutect2, varscan2
- APPL2 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1247118419; called by muse, mutect2, varscan2
- AQR | c.3052C>T p.R1018* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV50030477; called by muse, mutect2, varscan2
- ARAP2 | c.4211C>A p.S1404* | Nonsense Mutation (SNP) | VAF 38/228 reads (17%) | catalogued as COSV58284890; called by muse, mutect2, varscan2
- ARFRP1 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 55/301 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1568771304, COSV60832851; called by muse, mutect2, varscan2
- ARG2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs747904249, COSV104370240; called by muse, mutect2, varscan2
- ARHGAP23 | c.2957G>A p.R986Q | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779593713; called by muse, mutect2
- ARHGAP24 | c.1496G>A p.R499Q (on ENST00000395184 / NM_001025616.3; = p.R406Q on NM_031305.3) | Missense Mutation (SNP) | VAF 70/420 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.86); catalogued as rs115120658, COSV51994561; called by muse, mutect2, varscan2
- ARHGAP6 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as rs770470448; called by muse, varscan2
- ARHGDIB | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57456558; called by muse, mutect2
- ARHGEF10 | c.963G>T p.K321N (on ENST00000398564; = p.K296N on NM_014629.4) | Missense Mutation (SNP) | VAF 54/384 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV50658164; called by muse, mutect2, varscan2
- ARHGEF2 | c.332G>A p.R111Q (on ENST00000361247 / NM_001162383.2; = p.R84Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV58114003; called by muse, mutect2, varscan2
- ARHGEF26 | c.1534G>T p.D512Y | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1192765759; called by muse, mutect2, varscan2
- ARHGEF28 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs1391252105; called by muse, mutect2, varscan2
- ARHGEF4 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.224); catalogued as rs767784717, COSV58119639; called by muse, mutect2
- ARHGEF6 | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 53/369 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as rs565928900, COSV51690305; called by muse, mutect2, varscan2
- ARHGEF6 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs970851888, COSV51695337; called by muse, mutect2, varscan2
- ARHGEF6 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV51689074; called by muse, varscan2
- ARHGEF7 | c.2170G>A p.A724T (on ENST00000375741 / NM_001113511.2; = p.A546T on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs868583204, COSV54542791, COSV99521353; called by muse, mutect2
- ARID2 | c.2048G>T p.R683I | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV57600651; called by muse, mutect2, varscan2
- ARID4B | c.3175C>T p.R1059* | Nonsense Mutation (SNP) | VAF 71/199 reads (36%) | catalogued as COSV51599070, COSV51599207; called by muse, mutect2, varscan2
- ARL2BP | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 38/245 reads (16%) | catalogued as rs1207138391, COSV54656050; called by muse, mutect2, varscan2
- ARL5A | c.213A>C p.E71D | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.063); catalogued as rs1189090837; called by muse, varscan2
- ARMC2 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs760161977; called by muse, mutect2
- ARMC3 | c.1546G>T p.E516* | Nonsense Mutation (SNP) | VAF 31/163 reads (19%) | catalogued as rs776888309; called by muse, mutect2, varscan2
- ARMC4 | c.2810A>C p.K937T | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as COSV59468498; called by muse, mutect2, varscan2
- ARMC4 | c.861A>C p.K287N | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV53468388; called by muse, varscan2
- ARMC4 | c.857G>T p.R286I | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV53464084; called by muse, varscan2
- ARMC9 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201558091, COSV63022368; called by muse, mutect2, varscan2
- ARMCX2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs781783235, COSV57529674; called by muse, mutect2, varscan2
- ARMCX5 | c.1031C>T p.T344I | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55765924; called by muse, mutect2
- ARPP21 | c.1945T>C p.S649P | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV51800307; called by muse, mutect2, varscan2
- ARRB2 | c.1007T>C p.V336A | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV52617765; called by muse, mutect2, varscan2
- ARSL | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs369409927; called by muse, mutect2, varscan2
- ASCC3 | c.5149C>A p.L1717I | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1482481542, COSV100976913, COSV64975116; called by muse, mutect2
- ASH1L | c.4025G>A p.R1342Q | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs779477897; called by muse, varscan2
- ASH1L | c.3962G>A p.R1321Q | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs1358026443, COSV64205657; called by muse, varscan2
- ASIC5 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 18/182 reads (10%) | catalogued as rs1168515854, COSV73332699; called by muse, mutect2, varscan2
- ASPM | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 99/379 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs755695099; called by muse, mutect2, varscan2
- ASPN | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs146516859; called by muse, mutect2, varscan2
- ASTE1 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200808262, COSV53907523, COSV53908737; called by muse, mutect2, varscan2
- ASTN1 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs143274107, COSV56082666; called by muse, mutect2, varscan2
- ASTN2 | c.2272G>A p.E758K (on ENST00000313400 / NM_001365069.1; = p.E707K on NM_014010.5) | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as rs779197325, COSV57780493; called by muse, varscan2
- ASXL1 | c.4104G>T p.K1368N | Missense Mutation (SNP) | VAF 51/286 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60126432; called by muse, mutect2, varscan2
- ASXL3 | c.1611A>C p.L537F | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as COSV99326252; called by muse, varscan2
- ATAD2 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54884797, COSV99784553; called by muse, mutect2, varscan2
- ATAD2B | c.2725G>T p.E909* | Nonsense Mutation (SNP) | VAF 20/104 reads (19%) | catalogued as COSV99478104, COSV99478132; called by muse, mutect2, varscan2
- ATAD2B | c.728G>T p.R243I | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99478449; called by muse, varscan2
- ATG4C | c.530C>A p.S177Y | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.272); catalogued as COSV58609298; called by muse, mutect2, varscan2
- ATIC | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 62/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52695140; called by muse, mutect2, varscan2
- ATM | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769166447, CM1314652, COSV53734045, COSV53758870; ClinVar: uncertain significance; called by muse, varscan2
- ATM | c.7199G>T p.R2400I | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.219); catalogued as rs567457294, COSV53768686; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATMIN | c.1923C>A p.F641L | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV55146535; called by muse, mutect2, varscan2
- ATP10A | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs202137938, COSV100791177; called by muse, mutect2, varscan2
- ATP10A | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs751938420, COSV63517024; called by mutect2, varscan2
- ATP13A3 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs755718276, COSV55462722; called by muse, mutect2, varscan2
- ATP2B1 | c.2287C>T p.R763* | Nonsense Mutation (SNP) | VAF 22/156 reads (14%) | catalogued as COSV53805728; called by muse, mutect2, varscan2
- ATP2B4 | c.903T>C p.G301= | Splice Region (SNP) | VAF 25/136 reads (18%) | catalogued as rs746396969; called by muse, mutect2, varscan2
- ATP5F1E | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 66/334 reads (20%) | catalogued as rs376521812, COSV99414294; called by muse, mutect2, varscan2
- ATP5MC1 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 72/319 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs753944444, COSV63506024; called by muse, mutect2, varscan2
- ATP6AP1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs781904137; called by muse, mutect2
- ATP6V1A | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs778431937, COSV56361174; called by muse, mutect2, varscan2
- ATP8A1 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1217699790, COSV52531992; called by muse, mutect2, varscan2
- ATP8A2 | c.456G>T p.K152N | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54960468; called by muse, mutect2, varscan2
- ATP8B1 | c.2089G>T p.D697Y | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs762857853, COSV52173943; called by muse, mutect2
- ATP8B2 | c.1108G>A p.V370I (on ENST00000672630; = p.V337I on NM_001005855.2) | Missense Mutation (SNP) | VAF 71/522 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.244); catalogued as rs763046055; called by muse, mutect2, varscan2
- ATP9B | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs140291894, COSV56956164; called by muse, mutect2, varscan2
- ATR | c.4138G>T p.D1380Y | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as COSV63385516; called by muse, mutect2
- ATRIP | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57176887; called by muse, mutect2, varscan2
- ATRNL1 | c.2954G>A p.G985E | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.129); catalogued as rs868970016; called by muse, mutect2, varscan2
- ATRX | c.3819G>T p.K1273N | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64876068; called by muse, mutect2, varscan2
- ATRX | c.3392G>T p.R1131I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.259); catalogued as COSV64872016, COSV64874765; called by muse, mutect2
- ATXN1L | c.1531G>A p.V511M | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.83); catalogued as rs1365076603; called by muse, mutect2, varscan2
- ATXN7 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs780603764, COSV55753334; called by muse, mutect2, varscan2
- AVIL | c.2443G>T p.E815* | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | catalogued as COSV57680689; called by muse, mutect2, varscan2
- AXDND1 | c.1598A>G p.D533G | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100858231; called by muse, mutect2
- AXDND1 | c.2659G>T p.E887* | Nonsense Mutation (SNP) | VAF 18/200 reads (9%) | catalogued as COSV62650471; called by muse, mutect2
- B2M | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 52/275 reads (19%) | catalogued as COSV62563605; called by muse, mutect2, varscan2
- B3GAT1 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs1376263227; called by muse, mutect2, varscan2
- B3GAT3 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 64/469 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV55488411; called by muse, mutect2, varscan2
- B3GLCT | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 87/491 reads (18%) | catalogued as CM147012, COSV58454410; called by muse, mutect2, varscan2
- B3GNT2 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV100114059; called by muse, mutect2, varscan2
- B4GALNT4 | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 67/345 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV57321331; called by muse, mutect2, varscan2
- BACE1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs376235700; called by muse, mutect2, varscan2
- BACH1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs1257840097, COSV54517914; called by muse, mutect2, varscan2
- BACH1 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV54518055; called by muse, mutect2, varscan2
- BACH2 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs1250663291, COSV100000868, COSV57586295; called by muse, varscan2
- BAZ1B | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782811497; called by muse, mutect2, varscan2
- BBS12 | c.983C>A p.S328Y | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58561317, COSV58561950; called by muse, mutect2, varscan2
- BBS5 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV54751728; called by muse, mutect2, varscan2
- BBS9 | c.797G>T p.R266I | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV54174522; called by muse, mutect2, varscan2
- BCAN | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.404); catalogued as rs749562038; called by muse, mutect2, varscan2
- BCKDHB | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs933828560, COSV57511238; called by muse, mutect2
- BCL11B | c.233G>T p.R78M | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV61736327; called by muse, mutect2, varscan2
- BCL9 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 21/330 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.428); catalogued as rs782130973, COSV52342015; called by muse, mutect2
- BCL9 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 53/325 reads (16%) | catalogued as COSV52341987; called by muse, mutect2, varscan2
- BCL9 | c.2404G>T p.E802* | Nonsense Mutation (SNP) | VAF 66/448 reads (15%) | catalogued as COSV52341693; called by muse, mutect2, varscan2
- BDP1 | c.3623C>T p.S1208L | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as rs1354091586, COSV100702816, COSV62429915; called by muse, mutect2, varscan2
- BDP1 | c.4315A>G p.K1439E | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1444070603; called by muse, mutect2, varscan2
- BEND4 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 81/547 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs751350514, COSV72469111; called by muse, mutect2, varscan2
- BFAR | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.092); catalogued as rs1246290045; called by muse, mutect2, varscan2
- BFSP1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs774233789, COSV64900837; called by muse, mutect2, varscan2
- BIRC6 | c.4145G>A p.R1382Q | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.031); catalogued as rs777368785, COSV70196117; called by muse, mutect2, varscan2
- BIRC6 | c.12556C>T p.R4186* | Nonsense Mutation (SNP) | VAF 30/138 reads (22%) | catalogued as COSV70195557; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99958813; called by muse, mutect2, varscan2
- BLK | c.186C>A p.F62L | Missense Mutation (SNP) | VAF 59/428 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52056172; called by muse, mutect2, varscan2
- BMERB1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.525); catalogued as rs371464387, COSV55505605; called by mutect2, varscan2
- BMP15 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140319105, COSV99399328, COSV99399360; called by muse, mutect2, varscan2
- BMP5 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 42/190 reads (22%) | catalogued as COSV63706517; called by muse, mutect2, varscan2
- BMPR2 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs573463511; called by muse, mutect2, varscan2
- BMX | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 24/118 reads (20%) | catalogued as COSV59592185; called by muse, varscan2
- BMX | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs767957207, COSV59591844; called by muse, varscan2
- BNC1 | c.2476C>T p.R826* | Nonsense Mutation (SNP) | VAF 25/212 reads (12%) | catalogued as rs1270575850, COSV61757410; called by muse, mutect2, varscan2
- BNIP5 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as rs751045156; called by muse, mutect2, varscan2
- BPI | c.593G>A p.R198Q (on ENST00000262865; = p.R194Q on NM_001725.3) | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as rs749629986, COSV53404895, COSV53408318; called by muse, mutect2, varscan2
- BRCA1 | c.2704G>T p.E902* | Nonsense Mutation (SNP) | VAF 15/121 reads (12%) | catalogued as COSV100523802, COSV58796517; called by muse, mutect2, varscan2
- BRCA2 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as rs431825298; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- BRCA2 | c.9956C>A p.S3319Y | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.462); catalogued as rs778694116, COSV66336667; called by muse, mutect2, varscan2
- BRDT | c.858G>T p.K286N | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62864021, COSV62864626; called by muse, mutect2, varscan2
- BRI3BP | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 78/469 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs145269757; called by muse, mutect2, varscan2
- BRINP1 | c.190G>T p.G64* | Nonsense Mutation (SNP) | VAF 38/219 reads (17%) | catalogued as rs1263956698; called by muse, mutect2, varscan2
- BRWD1 | c.2905C>T p.R969* | Nonsense Mutation (SNP) | VAF 17/124 reads (14%) | catalogued as rs750289132, COSV60892937; called by muse, mutect2, varscan2
- BRWD3 | c.4627C>T p.R1543W | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs755270226, COSV64745068; called by muse, mutect2, varscan2
- BSDC1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs777929685; called by muse, mutect2, varscan2
- BST1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs760383985; called by muse, mutect2, varscan2
- BTBD8 | c.921C>A p.F307L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs758203077, COSV100730433, COSV61547145; called by muse, mutect2, varscan2
- BVES | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM160168, COSV58947039; called by muse, mutect2, varscan2
- C10orf120 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 51/311 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as rs756538058, COSV100271618; called by muse, mutect2, varscan2
- C10orf67 | c.958T>C p.S320P | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.892); catalogued as rs1233871678; called by muse, mutect2, varscan2
- C10orf90 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs763242638, COSV52949674; called by muse, mutect2, varscan2
- C12orf4 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as COSV99713035; called by muse, mutect2, varscan2
- C12orf56 | c.1756G>T p.E586* (on ENST00000543942 / NM_001170633.2; = p.E426* on NM_001099676.3) | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as rs1360425650, COSV100399546; called by muse, mutect2, varscan2
- C12orf56 | c.1276G>A p.E426K (on ENST00000543942 / NM_001170633.2; = p.E266K on NM_001099676.3) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs762041250, COSV100398970; called by mutect2, varscan2
- C12orf56 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 32/210 reads (15%) | catalogued as COSV61486807; called by muse, varscan2
- C14orf28 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as rs765434415; called by muse, mutect2, varscan2
- C14orf39 | c.1364G>T p.R455I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV58781496, COSV58781699; called by muse, mutect2
- C16orf89 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 73/278 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1301302453, COSV60122446; called by muse, mutect2, varscan2
- C16orf92 | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV54228206, COSV54228303; called by muse, mutect2, varscan2
- C17orf80 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 55/363 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as rs142702679; called by muse, mutect2, varscan2
- C19orf44 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs563097198, COSV99522125; called by muse, mutect2, varscan2
- C1QTNF2 | c.323C>A p.P108H (on ENST00000393975; = p.P63H on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101220891; called by muse, mutect2, varscan2
- C1orf116 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs755460908, COSV63943892; called by muse, mutect2, varscan2
- C1orf141 | c.407G>T p.R136I | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100924331, COSV63993215; called by muse, mutect2, varscan2
- C1orf141 | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 31/174 reads (18%) | catalogued as COSV63992921; called by mutect2, varscan2
- C1orf87 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs954642126, COSV64596002; called by muse, mutect2
- C20orf202 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 18/104 reads (17%) | catalogued as rs866769135, COSV68763909; called by muse, mutect2, varscan2
- C22orf23 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 28/248 reads (11%) | catalogued as COSV50777637; called by muse, mutect2, varscan2
- C2CD2L | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.588); catalogued as COSV100371332; called by muse, mutect2, varscan2
- C2CD6 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs370301019; called by muse, mutect2, varscan2
- C3 | c.2035C>T p.R679* | Nonsense Mutation (SNP) | VAF 55/340 reads (16%) | catalogued as COSV55570751; called by muse, mutect2, varscan2
- C4BPA | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.373); catalogued as rs1366967873, COSV65535824, COSV65537022; called by muse, mutect2
- C4BPA | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 21/145 reads (14%) | catalogued as rs1215951903, COSV65535588; called by muse, mutect2, varscan2
- C4BPA | c.1786G>T p.E596* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as COSV65536707; called by muse, mutect2
- C4orf54 | c.3604C>T p.P1202S | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV72766773; called by muse, mutect2, varscan2
- C5orf34 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs751051116, COSV60931222; called by muse, mutect2, varscan2
- C6orf118 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.055); catalogued as rs1189765141; called by muse, mutect2, varscan2
- C7orf31 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV99383738; called by muse, mutect2
- C8orf37 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs149558233; called by muse, mutect2, varscan2
- C8orf88 | c.227G>T p.R76I | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104434580; called by muse, mutect2
- C9orf131 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 42/294 reads (14%) | catalogued as rs144687989, COSV56610059; called by muse, mutect2, varscan2
- CA2 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV53407154; called by muse, mutect2, varscan2
- CA4 | c.786G>T p.Q262H | Missense Mutation (SNP) | VAF 71/445 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV56282861; called by muse, mutect2, varscan2
- CABS1 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as COSV56734215; called by muse, mutect2, varscan2
- CACNA1C | c.4610G>A p.R1537H | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1455468826, COSV100222098, COSV59738753; called by muse, mutect2
- CACNA1D | c.3829G>A p.V1277I (on ENST00000350061 / NM_001128840.3; = p.V1297I on NM_000720.4) | Missense Mutation (SNP) | VAF 73/538 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1329352704, COSV55445896; called by muse, varscan2
- CACNA1E | c.4066G>A p.D1356N | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1305669747, COSV62391690; called by muse, mutect2, varscan2
- CACNA1E | c.4820T>G p.L1607R | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100704317; called by muse, mutect2, varscan2
- CACNA1F | c.4008G>T p.M1336I | Missense Mutation (SNP) | VAF 57/400 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV59907208; called by muse, mutect2, varscan2
- CACNA1S | c.1530G>T p.E510D | Missense Mutation (SNP) | VAF 102/359 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as rs758354862, COSV62941296; called by muse, mutect2, varscan2
- CACNA1S | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 142/533 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs370861322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNB1 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1449261961; called by muse, mutect2, varscan2
- CACUL1 | c.626G>T p.R209I | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV60994905; called by muse, mutect2, varscan2
- CADPS | c.3256G>T p.E1086* | Nonsense Mutation (SNP) | VAF 38/259 reads (15%) | catalogued as COSV51891569; called by muse, mutect2, varscan2
- CALHM5 | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.137); catalogued as COSV62068241; called by muse, mutect2, varscan2
- CALU | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs1240643484; called by muse, mutect2, varscan2
- CAMK2B | c.1700C>T p.S567L | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); catalogued as rs981667182, COSV99323036; called by muse, mutect2, varscan2
- CAMK2D | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as rs1194393580; called by muse, varscan2
- CAPN13 | c.1523G>A p.R508K | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1391044979; called by muse, mutect2, varscan2
- CAPN6 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100136965; called by muse, mutect2
- CAPN9 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs770366418, COSV55241971; called by muse, mutect2, varscan2
- CAPRIN2 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs763676110, COSV51830525; called by muse, mutect2, varscan2
- CAPZA2 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV63265905; called by muse, mutect2
- CASK | c.1573C>A p.H525N | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100586869; called by muse, mutect2, varscan2
- CASP14 | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV99693129; called by muse, mutect2, varscan2
- CASP14 | c.584T>C p.F195S | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55664838; called by muse, mutect2, varscan2
- CASP6 | c.296A>C p.K99T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.111); catalogued as COSV54460401; called by mutect2, varscan2
- CASP8 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs1339962485, COSV51846409, COSV51847390, COSV51855757; called by muse, varscan2
- CASQ2 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 46/330 reads (14%) | catalogued as COSV54774838; called by muse, mutect2, varscan2
- CASS4 | c.1639C>A p.L547I | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444501272; called by muse, mutect2, varscan2
- CATSPERB | c.1012C>A p.L338I | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs754792783, COSV56421740; called by muse, varscan2
- CBLN3 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs760763185, COSV52160248; called by muse, mutect2, varscan2
- CBY2 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.046); catalogued as rs1171465321, COSV100137892; called by muse, mutect2, varscan2
- CCDC138 | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs780781321; called by muse, mutect2, varscan2
- CCDC159 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 20/295 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV100712306; called by muse, mutect2
- CCDC160 | c.251G>T p.R84I | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66251612, COSV66251844; called by muse, mutect2, varscan2
- CCDC168 | c.18176G>T p.R6059I | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); catalogued as COSV59420079; called by muse, mutect2, varscan2
- CCDC171 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as COSV52634848; called by muse, varscan2
- CCDC175 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1305679219; called by muse, mutect2, varscan2
- CCDC18 | c.1887T>G p.I629M (on ENST00000343253 / NM_001306076.1; = p.I630M on NM_206886.4) | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs1352362103; called by muse, mutect2, varscan2
- CCDC181 | c.1146G>T p.K382N | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV63156119; called by muse, mutect2, varscan2
- CCDC191 | c.161C>A p.S54* | Nonsense Mutation (SNP) | VAF 24/112 reads (21%) | catalogued as COSV99878614; called by muse, mutect2, varscan2
- CCDC3 | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV104430437; called by muse, varscan2
- CCDC30 | c.917G>A p.R306Q (on ENST00000340612; = p.R263Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.884); catalogued as rs759851719, COSV59607235; called by muse, mutect2, varscan2
- CCDC30 | c.990G>T p.K330N (on ENST00000340612; = p.K287N on NM_001080850.3) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as COSV59605182; called by muse, mutect2
- CCDC39 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV56489373; called by muse, mutect2
- CCDC50 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV66667794; called by muse, mutect2, varscan2
- CCDC66 | c.2280T>G p.I760M (on ENST00000394672 / NM_001353147.1; = p.I726M on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV58306508; called by muse, mutect2
- CCDC66 | c.2650C>T p.R884* (on ENST00000394672 / NM_001353147.1; = p.R850* on NM_001012506.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 23/103 reads (22%) | catalogued as rs371423664; called by muse, mutect2, varscan2
- CCDC80 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs759648511, COSV52815608; called by muse, mutect2, varscan2
- CCDC81 | c.1004G>A p.R335Q (on ENST00000445632 / NM_001156474.2; = p.R245Q on NM_021827.4) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs868030464, COSV53577858; called by muse, mutect2
- CCDC85A | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV68154572; called by muse, mutect2, varscan2
- CCDC85A | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs765502186, COSV101339350, COSV68149842; called by muse, mutect2, varscan2
- CCDC88A | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs769621745, COSV55069328; called by muse, mutect2, varscan2
- CCDC96 | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 34/191 reads (18%) | catalogued as rs753773609, COSV59508510; called by muse, mutect2, varscan2
- CCL3 | c.63C>A p.F21L | Missense Mutation (SNP) | VAF 56/419 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs536802779; called by muse, mutect2, varscan2
- CCL7 | c.298T>C p.*100Rext*16 | Nonstop Mutation (SNP) | VAF 30/213 reads (14%) | catalogued as rs1243752647; called by muse, mutect2, varscan2
- CCNB3 | c.2030C>A p.S677* | Nonsense Mutation (SNP) | VAF 14/170 reads (8%) | catalogued as COSV99329927; called by muse, mutect2
- CCNH | c.590G>T p.R197I | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV56924642; called by muse, mutect2
- CCT8 | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 24/149 reads (16%) | catalogued as COSV54505961; called by muse, mutect2, varscan2
- CD163 | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765869382, COSV63136320; called by muse, mutect2, varscan2
- CD163 | c.1343C>A p.S448Y | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.985); catalogued as COSV100776091, COSV63133773; called by muse, mutect2, varscan2
- CD163L1 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 51/326 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58013857; called by muse, mutect2, varscan2
- CD207 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 88/398 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781939546, COSV69651807; called by muse, mutect2, varscan2
- CD276 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as COSV100573442; called by muse, mutect2, varscan2
- CD300LD | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs781234456; called by muse, mutect2, varscan2
- CD55 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as CM076088, COSV58576670; called by muse, mutect2, varscan2
- CD58 | c.348C>A p.F116L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as COSV65665231; called by muse, mutect2
- CD80 | c.57C>A p.F19L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1203312130, COSV51801388, COSV51802025; called by muse, mutect2, varscan2
- CDC14C | c.899G>A p.R300Q (on ENST00000428251; = p.R193Q on NM_152627.3) | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs544447682; called by muse, mutect2, varscan2
- CDC25C | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 19/98 reads (19%) | catalogued as COSV60400561, COSV60401199; called by muse, mutect2, varscan2
- CDC37L1 | c.607C>A p.H203N | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV67866067; called by muse, mutect2, varscan2
- CDC40 | c.1503T>G p.I501M | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.326); catalogued as COSV57008844; called by muse, mutect2, varscan2
- CDC42BPB | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63477002; called by muse, mutect2, varscan2
- CDC7 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs375702482, COSV52309241, COSV99319834; called by mutect2, varscan2
- CDC7 | c.1217C>A p.S406Y | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52310167; called by muse, mutect2
- CDH10 | c.835C>A p.L279I | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as COSV100051544, COSV52581723; called by muse, mutect2
- CDH10 | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs545638636, COSV52579683, COSV52599865; called by muse, mutect2, varscan2
- CDH18 | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 25/112 reads (22%) | catalogued as rs764848176, COSV56904459; called by muse, mutect2
- CDH2 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 34/158 reads (22%) | catalogued as rs748735492, COSV52271435; called by muse, varscan2
- CDH7 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59883306; called by muse, varscan2
- CDH7 | c.1447G>C p.A483P | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.048); catalogued as COSV59895639; called by muse, mutect2, varscan2
- CDH7 | c.1768G>A p.V590I | Missense Mutation (SNP) | VAF 68/408 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs141957522, COSV59888622; called by muse, mutect2, varscan2
- CDH9 | c.2255C>A p.S752Y | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179587887, COSV50266617, COSV50276802; called by muse, mutect2, varscan2
- CDH9 | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1355743507, COSV50504639; called by muse, mutect2, varscan2
- CDHR1 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs201649854; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2641G>A p.D881N | Missense Mutation (SNP) | VAF 95/604 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs766761953, COSV62572165; ClinVar: uncertain significance; called by muse, varscan2
- CDKL5 | c.1985C>A p.S662Y | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.34); catalogued as COSV66110766; called by muse, mutect2
- CDR2L | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.459); catalogued as rs540497526; called by muse, mutect2
- CDRT1 | c.2042G>T p.R681I | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.766); catalogued as COSV63053063, COSV63054201; called by muse, mutect2
- CDS1 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1295525014; called by mutect2, varscan2
- CDX4 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868321760, COSV65171686; called by muse, mutect2, varscan2
- CEBPZ | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV50017275; called by muse, mutect2, varscan2
- CECR2 | c.3140C>T p.S1047L (on ENST00000342247 / NM_001290047.2; = p.S863L on NM_001290046.1) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs574553165, COSV52840788, COSV52841035; called by muse, mutect2, varscan2
- CELF2 | c.419C>T p.S140L (on ENST00000416382 / NM_001025077.3; = p.S147L on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746403544, COSV59971344; called by muse, mutect2, varscan2
- CEMIP | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as rs756288191, COSV54993786; called by muse, mutect2, varscan2
- CENPC | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56622895; called by muse, mutect2
- CENPE | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1287350091, COSV54392180; called by muse, mutect2, varscan2
- CENPF | c.2845G>A p.E949K | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs543055880, COSV65273439; called by muse, mutect2, varscan2
- CEP126 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | catalogued as COSV54827338, COSV54831336; called by muse, mutect2, varscan2
- CEP135 | c.2209G>T p.D737Y | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99954226; called by muse, mutect2, varscan2
- CEP162 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs773293017, COSV57620079; called by muse, varscan2
- CEP170B | c.1227C>A p.F409L (on ENST00000453495; = p.F338L on NM_015005.3) | Missense Mutation (SNP) | VAF 67/396 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV101371517; called by muse, mutect2, varscan2
- CEP192 | c.7400C>A p.S2467Y | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1169473037, COSV58062657; called by muse, mutect2, varscan2
- CEP295 | c.5259C>A p.F1753L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.135); catalogued as COSV100292406; called by muse, mutect2
- CEP350 | c.4873C>T p.R1625* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | catalogued as rs1181129362, COSV62601953; called by muse, mutect2, varscan2
- CEP350 | c.9271G>A p.G3091R | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs542770010, COSV62603218; called by muse, mutect2, varscan2
- CEP76 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.669); catalogued as rs766046312, COSV50867864; called by mutect2, varscan2
- CEP83 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.178); catalogued as rs587777487, CM145883, COSV60409884; called by muse, mutect2, varscan2
- CEP83 | c.919A>G p.T307A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1258947428, COSV60408062; called by muse, varscan2
- CEP85 | c.1242G>T p.K414N | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV53327451; called by muse, mutect2, varscan2
- CEP85L | c.1828G>T p.D610Y | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV63828934; called by muse, mutect2, varscan2
- CEP97 | c.2081C>A p.S694* | Nonsense Mutation (SNP) | VAF 19/126 reads (15%) | catalogued as COSV59126391; called by muse, mutect2, varscan2
- CERS3 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs904261909, COSV52564617; called by muse, mutect2, varscan2
- CES4A | c.693G>T p.M231I | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs1010655248; called by muse, mutect2, varscan2
- CES5A | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV99307662; called by muse, varscan2
- CFAP36 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as rs763494988, COSV59117634; called by muse, mutect2, varscan2
- CFAP43 | c.3145C>T p.R1049* | Nonsense Mutation (SNP) | VAF 36/230 reads (16%) | catalogued as rs761189614, COSV53376518; called by muse, varscan2
- CFAP43 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs372598864, COSV53376197; called by muse, varscan2
- CFAP44 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs377623503; called by muse, varscan2
- CFAP44 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs776191039, COSV55608483; called by muse, mutect2, varscan2
- CFAP54 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100127603; called by muse, mutect2
- CFAP54 | c.3209G>T p.R1070I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1395849963; called by muse, mutect2
- CFAP54 | c.3296A>G p.K1099R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.195); catalogued as rs1375177695; called by muse, mutect2, varscan2
- CFAP57 | c.3223C>T p.R1075* (on ENST00000372492 / NM_001378189.1; = p.R1108* on NM_001195831.3) | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | catalogued as rs1383479936, COSV65263701; called by muse, mutect2, varscan2
- CFAP65 | c.51G>T p.E17D | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.056); catalogued as COSV55389276; called by muse, mutect2, varscan2
- CFAP69 | c.2254C>A p.L752I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV60188695; called by muse, mutect2
- CFAP91 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs200409004; called by muse, varscan2
- CFAP94 | c.1104C>A p.F368L (on ENST00000320267 / NM_001352064.2; = p.F374L on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.023); catalogued as rs1013340991, COSV57230587; called by muse, mutect2, varscan2
- CFAP97 | c.128G>T p.R43I | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV57109307; called by muse, mutect2, varscan2
- CFAP99 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 51/330 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.297); catalogued as rs781551306; called by muse, mutect2, varscan2
- CFH | c.2521G>T p.E841* | Nonsense Mutation (SNP) | VAF 56/213 reads (26%) | catalogued as COSV66412622; called by muse, mutect2, varscan2
- CFHR1 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 130/549 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as rs267598271; called by muse, mutect2, varscan2
- CFHR2 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV66380783; called by muse, varscan2
- CFHR3 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.482); catalogued as COSV66402046; called by muse, varscan2
- CFHR4 | c.175T>G p.F59V (on ENST00000367416 / NM_001201551.2; = p.F60V on NM_006684.5) | Missense Mutation (SNP) | VAF 41/269 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1163378982, COSV52227034; called by muse, mutect2, varscan2
- CFHR5 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 24/246 reads (10%) | catalogued as COSV56828387; called by muse, mutect2, varscan2
- CFTR | c.2094G>T p.K698N | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50084965; called by muse, mutect2, varscan2
- CGAS | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as COSV64807949; called by muse, mutect2, varscan2
- CGN | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 80/323 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs768433517; called by muse, mutect2, varscan2
- CHAF1B | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs764986563; called by muse, mutect2, varscan2
- CHCHD3 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 21/157 reads (13%) | catalogued as COSV99366252; called by muse, mutect2, varscan2
- CHD2 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV59119156; called by muse, mutect2
- CHD4 | c.3241G>A p.E1081K (on ENST00000357008 / NM_001363606.2; = p.E1094K on NM_001273.5) | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV58894162; called by muse, mutect2, varscan2
- CHD4 | c.1059G>T p.K353N | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs867213835; called by muse, mutect2, varscan2
- CHD7 | c.3041G>A p.G1014E | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV71114189; called by muse, mutect2
- CHD8 | c.4204C>T p.R1402* (on ENST00000646647 / NM_001170629.2; = p.R1123* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 16/140 reads (11%) | catalogued as rs1334692966, COSV63219087; called by muse, mutect2
- CHD8 | c.2004C>A p.F668L (on ENST00000646647 / NM_001170629.2; = p.F389L on NM_020920.4) | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs1445246220, COSV67869656; called by muse, varscan2
- CHD9 | c.4177G>T p.E1393* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99529882; called by muse, mutect2, varscan2
- CHGB | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 44/280 reads (16%) | catalogued as COSV66760746; called by muse, mutect2, varscan2
- CHI3L2 | c.1050G>T p.K350N | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63874091, COSV63874411, COSV63874941; called by muse, mutect2, varscan2
- CHML | c.1595C>A p.P532Q | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.633); catalogued as COSV59366569; called by muse, mutect2, varscan2
- CHPF2 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99223105; called by muse, mutect2, varscan2
- CHRNB2 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 160/612 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140505576; called by muse, mutect2, varscan2
- CHST15 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 93/359 reads (26%) | catalogued as COSV60560141, COSV60560330; called by muse, varscan2
- CIBAR2 | c.438G>T p.E146D | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs771770710; called by muse, mutect2, varscan2
- CILK1 | c.1501C>T p.R501* (on ENST00000350082 / NM_001375397.1; = p.R494* on NM_014920.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 63/432 reads (15%) | catalogued as rs755230589, COSV63154041; called by muse, mutect2, varscan2
- CILP | c.2848G>T p.E950* | Nonsense Mutation (SNP) | VAF 39/220 reads (18%) | catalogued as COSV56024178; called by muse, mutect2, varscan2
- CIR1 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs113242892; called by muse, mutect2, varscan2
- CIT | c.4495G>A p.D1499N | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as rs747537867, COSV55864803; called by muse, mutect2, varscan2
- CKAP2L | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs372791577; called by muse, mutect2, varscan2
- CKAP5 | c.5496C>A p.F1832L (on ENST00000529230 / NM_001008938.4; = p.F1772L on NM_014756.3) | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100371554; called by muse, mutect2, varscan2
- CLASP1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 28/173 reads (16%) | catalogued as rs1189932217, COSV55313347; called by muse, mutect2, varscan2
- CLASP2 | c.3329C>T p.S1110F (on ENST00000359576; = p.S1109F on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); catalogued as COSV56286958; called by muse, mutect2, varscan2
- CLCA2 | c.409A>C p.K137Q | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.682); catalogued as rs755230858; called by muse, mutect2, varscan2
- CLCA2 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.396); catalogued as COSV100991319; called by muse, mutect2, varscan2
- CLCN1 | c.2264C>A p.P755Q | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); catalogued as CD972138; called by muse, mutect2, varscan2
- CLCN1 | c.2299A>G p.I767V | Missense Mutation (SNP) | VAF 66/393 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1232912512; called by muse, mutect2, varscan2
- CLCN4 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 45/346 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs761767858, COSV66467646; called by muse, mutect2, varscan2
- CLCN7 | c.2140G>A p.A714T | Missense Mutation (SNP) | VAF 218/775 reads (28%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.557); catalogued as rs767382071, COSV99247187; called by muse, mutect2, varscan2
- CLDN8 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54525723; called by muse, mutect2, varscan2
- CLDND1 | c.123A>C p.E41D | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.749); catalogued as COSV100360829; called by muse, mutect2, varscan2
- CLEC14A | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV60563629; called by muse, mutect2, varscan2
- CLEC1A | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100191377; called by muse, mutect2
- CLEC4C | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.759); catalogued as COSV63582424; called by muse, mutect2, varscan2
- CLIC2 | c.519C>A p.F173L | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs781997025, COSV58936394; called by muse, mutect2, varscan2
- CLIP1 | c.2511A>T p.E837D (on ENST00000620786 / NM_001247997.1; = p.E826D on NM_002956.2) | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV56800548; called by mutect2, varscan2
- CLN3 | c.838G>A p.E280K (on ENST00000360019 / NM_001286104.2; = p.E304K on NM_000086.2) | Missense Mutation (SNP) | VAF 99/570 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61104770; called by muse, mutect2, varscan2
- CLRN2 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs374428888; called by muse, mutect2, varscan2
- CLSPN | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52048832; called by muse, mutect2, varscan2
- CLTC | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 51/318 reads (16%) | catalogued as COSV99291998; called by muse, mutect2, varscan2
- CLUH | c.1234G>A p.E412K (on ENST00000435359; = p.E450K on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1455565845; called by muse, mutect2, varscan2
- CMAS | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 28/139 reads (20%) | catalogued as rs1223698463, COSV57556874; called by muse, mutect2, varscan2
- CMAS | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs189328375, COSV57556563; called by muse, mutect2, varscan2
- CMC4 | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100749832; called by muse, mutect2
- CMSS1 | c.711G>A p.W237* | Nonsense Mutation (SNP) | VAF 10/180 reads (6%) | catalogued as COSV70439538; called by muse, mutect2
- CMYA5 | c.6141C>A p.F2047L | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV71405034; called by muse, mutect2, varscan2
- CMYA5 | c.7100G>T p.R2367I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV71406089; called by muse, mutect2, varscan2
- CMYA5 | c.8896G>A p.D2966N | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs959129009, COSV71404032; called by muse, mutect2, varscan2
- CNGA2 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs149746449, COSV61704016; called by muse, mutect2, varscan2
- CNGA2 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs959972258, COSV61706168; called by muse, varscan2
- CNGA2 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs758699633, COSV61705411; called by muse, varscan2
- CNGA3 | c.1969A>C p.K657Q | Missense Mutation (SNP) | VAF 62/281 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV55624743; called by muse, mutect2, varscan2
- CNGA4 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 85/592 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs149747380; called by muse, mutect2, varscan2
- CNKSR2 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1569272190, COSV54262591; called by muse, mutect2, varscan2
- CNN3 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as rs891411357, COSV64637535; called by muse, mutect2, varscan2
- CNOT8 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 27/216 reads (13%) | catalogued as COSV99597205; called by muse, mutect2, varscan2
- CNR2 | c.777C>A p.F259L | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV65693423; called by mutect2, varscan2
- CNTN1 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs773587445, COSV61638896; called by muse, varscan2
- CNTN1 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.564); catalogued as rs755978506, COSV100751856; called by muse, varscan2
- CNTN3 | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55164503, COSV55171000; called by muse, mutect2, varscan2
- CNTN5 | c.3136C>T p.R1046* | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as rs371358971; called by muse, mutect2, varscan2
- CNTNAP1 | c.2798C>T p.A933V | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs777042333, COSV104390772; called by muse, mutect2, varscan2
- CNTNAP2 | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV100672540, COSV62185665; called by muse, mutect2, varscan2
- CNTNAP2 | c.2509C>A p.L837I | Missense Mutation (SNP) | VAF 47/317 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV100664934; called by muse, mutect2, varscan2
- CNTNAP4 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100272258; called by muse, mutect2, varscan2
- CNTNAP4 | c.2252G>T p.G751V | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV100269710; called by muse, mutect2, varscan2
- CNTNAP4 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs764763387, COSV56673375; called by mutect2, varscan2
- CNTNAP5 | c.200G>T p.W67L | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200770909; called by muse, varscan2
- CNTNAP5 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.978); catalogued as COSV70484907; called by muse, mutect2, varscan2
- COA8 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as COSV56027321, COSV99914704; called by muse, mutect2, varscan2
- COBL | c.3276G>T p.K1092N | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54357743; called by muse, mutect2, varscan2
- COG8 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 74/414 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV55341013; called by muse, varscan2
- COL11A1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.905); catalogued as rs1341498364, COSV62186825; called by muse, varscan2
- COL11A2 | c.5006C>A p.A1669D (on ENST00000341947 / NM_080680.3; = p.A1562D on NM_080679.2) | Missense Mutation (SNP) | VAF 64/393 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.924); catalogued as COSV100554425; called by muse, mutect2, varscan2
- COL12A1 | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); catalogued as rs377480187, CM1511987; called by muse, mutect2, varscan2
- COL17A1 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 51/377 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs763635529; called by muse, mutect2, varscan2
- COL21A1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs181443791; called by muse, mutect2, varscan2
- COL27A1 | c.2634G>C p.L878F | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.759); catalogued as COSV100621431; called by muse, mutect2, varscan2
- COL4A2 | c.3270C>T p.F1090= | Splice Region (SNP) | VAF 49/319 reads (15%) | catalogued as rs762951574, COSV64627172; called by muse, mutect2, varscan2
- COL5A1 | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 60/427 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV65669211; called by muse, mutect2, varscan2
- COL5A1 | c.4201G>A p.E1401K | Missense Mutation (SNP) | VAF 56/322 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1370262542, COSV100879366, COSV65668107; called by muse, varscan2
- COL5A2 | c.4462G>T p.E1488* | Nonsense Mutation (SNP) | VAF 24/515 reads (5%) | catalogued as COSV66408502; called by muse, mutect2
- COL5A3 | c.5122G>A p.E1708K | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs563109290, COSV53409530; called by muse, varscan2
- COL6A2 | c.2798G>A p.R933H | Missense Mutation (SNP) | VAF 71/396 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.494); catalogued as rs374384263; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL6A3 | c.6979G>A p.E2327K | Missense Mutation (SNP) | VAF 61/526 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs1435064229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.4561G>A p.E1521K | Missense Mutation (SNP) | VAF 97/418 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.59); catalogued as rs113538665, COSV55107615; called by muse, mutect2, varscan2
- COL6A3 | c.3145G>A p.E1049K | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV99800708; called by muse, mutect2, varscan2
- COL6A3 | c.1588G>T p.D530Y | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV55105180; called by muse, varscan2
- COL6A5 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.823); catalogued as COSV99593808; called by muse, mutect2, varscan2
- COL6A5 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55215461; called by muse, mutect2, varscan2
- COL6A5 | c.2068G>T p.E690* | Nonsense Mutation (SNP) | VAF 24/138 reads (17%) | catalogued as COSV55195686, COSV55196777; called by muse, mutect2, varscan2
- COL6A5 | c.2254C>T p.R752W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393082594, COSV55199959; called by muse, mutect2, varscan2
- COL6A5 | c.4294G>A p.D1432N | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.499); catalogued as COSV55214311; called by muse, mutect2, varscan2
- COL6A5 | c.4387C>A p.H1463N | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.029); catalogued as COSV55218446; called by muse, mutect2
- COL7A1 | c.4660G>T p.G1554* | Nonsense Mutation (SNP) | VAF 107/552 reads (19%) | catalogued as COSV60403419; called by muse, mutect2, varscan2
- COL9A1 | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0.014); catalogued as rs1334455354; called by muse, mutect2, varscan2
- COL9A2 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 75/491 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.207); catalogued as rs747104088; called by muse, mutect2, varscan2
- COLEC10 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773596648, COSV60520914; called by muse, mutect2, varscan2
- COLEC12 | c.2116G>T p.E706* | Nonsense Mutation (SNP) | VAF 30/217 reads (14%) | catalogued as COSV101232100; called by muse, varscan2
- COPA | c.3588C>A p.F1196L | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV54100297; called by muse, mutect2, varscan2
- COPB2 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as rs745747191, COSV100169028; called by mutect2, varscan2
- COPB2 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 13/87 reads (15%) | catalogued as COSV60813222; called by muse, mutect2
- COPG2 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs1263188076; called by muse, mutect2, varscan2
- COQ2 | c.637C>A p.L213I | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61022012; called by muse, mutect2, varscan2
- CORO7 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 99/378 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs766048891, COSV99227222; called by muse, mutect2, varscan2
- CPA1 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1554411204; called by muse, mutect2
- CPAMD8 | c.4775C>T p.A1592V (on ENST00000651564; = p.A1545V on NM_015692.5) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs747033120; called by muse, mutect2, varscan2
- CPAMD8 | c.3056G>A p.R1019H (on ENST00000651564; = p.R972H on NM_015692.5) | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs547742402; called by muse, mutect2, varscan2
- CPE | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68579224; called by muse, mutect2
- CPLANE1 | c.8711G>A p.R2904Q | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as rs533791946, COSV57055392; called by muse, varscan2
- CPSF3 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 17/94 reads (18%) | catalogued as rs199913516; called by muse, mutect2, varscan2
- CR1 | c.4033G>T p.E1345* | Nonsense Mutation (SNP) | VAF 41/365 reads (11%) | catalogued as COSV100887649; called by muse, mutect2, varscan2
- CR2 | c.723C>A p.F241L | Missense Mutation (SNP) | VAF 43/406 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV100889516, COSV65506872; called by muse, mutect2, varscan2
- CRACD | c.1672G>A p.V558M | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767475512, COSV51731824; called by muse, mutect2, varscan2
- CRACDL | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967032367, COSV67408722; called by muse, varscan2
- CREBBP | c.3956G>A p.R1319Q | Missense Mutation (SNP) | VAF 129/475 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1252438256, COSV52113834; called by muse, mutect2, varscan2
- CREBBP | c.3505C>T p.R1169C | Missense Mutation (SNP) | VAF 86/558 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52115098; called by muse, mutect2, varscan2
- CRISPLD1 | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs762231023, COSV100081812, COSV100082100; called by muse, mutect2, varscan2
- CRMP1 | c.811+1G>A p.X271_splice | Splice Site (SNP) | VAF 44/342 reads (13%) | catalogued as COSV61483432; called by muse, mutect2, varscan2
- CRYBA4 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 95/601 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1379946401, COSV61322341; called by muse, mutect2, varscan2
- CRYBG1 | c.5701C>T p.R1901C | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779661246; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1013C>A p.S338* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as COSV65675590; called by muse, mutect2, varscan2
- CSMD2 | c.9434C>T p.S3145F | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as COSV53874473, COSV53882363; called by muse, mutect2
- CSMD3 | c.7126G>T p.D2376Y (on ENST00000297405 / NM_001363185.1; = p.D2272Y on NM_052900.3) | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52123755, COSV52196691; called by muse, mutect2, varscan2
- CSMD3 | c.1946C>A p.S649Y (on ENST00000297405 / NM_001363185.1; = p.S545Y on NM_052900.3) | Missense Mutation (SNP) | VAF 24/329 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV52317597; called by muse, mutect2
- CSNK1A1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV55792565; called by muse, mutect2, varscan2
- CSNK2A3 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 67/454 reads (15%) | catalogued as rs1564906387, COSV99924132, COSV99924826; called by muse, mutect2, varscan2
- CSPG4 | c.4093T>G p.F1365V | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.063); catalogued as rs987355927; called by muse, mutect2, varscan2
- CTDSP2 | c.246C>A p.F82L | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101143118; called by muse, mutect2, varscan2
- CTDSPL2 | c.1189C>A p.L397I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52945446, COSV52947505; called by mutect2, varscan2
- CTSC | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773090897, COSV57058229; called by muse, mutect2, varscan2
- CUEDC2 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.694); catalogued as rs778175495, COSV50045262; called by muse, mutect2, varscan2
- CUL2 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV66078252; called by muse, mutect2, varscan2
- CUL7 | c.1831G>T p.E611* | Nonsense Mutation (SNP) | VAF 25/152 reads (16%) | catalogued as COSV54818996; called by muse, mutect2, varscan2
- CUZD1 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 73/309 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV59025542; called by muse, mutect2, varscan2
- CWC22 | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as COSV55430747; called by muse, mutect2, varscan2
- CWH43 | c.365G>T p.R122I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs550223498; called by muse, mutect2
- CXorf38 | c.563T>G p.F188C | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59947255; called by muse, mutect2, varscan2
- CXorf65 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1400422107; called by muse, mutect2
- CYBB | c.117C>A p.F39L | Missense Mutation (SNP) | VAF 41/371 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV101059796, COSV66084945, COSV66085645; called by muse, mutect2, varscan2
- CYFIP1 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs778294512; called by muse, mutect2, varscan2
- CYFIP2 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 17/156 reads (11%) | catalogued as rs868243549, COSV59030613, COSV59050697; called by muse, mutect2, varscan2
- CYLC2 | c.248G>T p.R83I | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV66337690; called by muse, mutect2, varscan2
- CYLC2 | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV66336937; called by muse, mutect2, varscan2
- CYP21A2 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 206/1209 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs760216630, CM990465, COSV64490722; called by muse, mutect2, varscan2
- CYP24A1 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs571886397, COSV53773343; called by muse, mutect2, varscan2
- CYP27C1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs1418713591, COSV58866324; called by muse, mutect2, varscan2
- CYP27C1 | c.95G>T p.R32I | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100079991, COSV58866752; called by muse, mutect2, varscan2
- CYP2A13 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs777216350; called by muse, mutect2, varscan2
- CYP2C9 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs772782449; called by muse, mutect2, varscan2
- CYP2R1 | c.970C>A p.L324I | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58126599; called by muse, mutect2, varscan2
- CYP4V2 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs894863416, COSV66505057; called by muse, mutect2, varscan2
- CYP51A1 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs776540678, COSV50151372; called by muse, mutect2, varscan2
- CYP7B1 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59585928, COSV59596985; called by muse, mutect2, varscan2
- DAAM2 | c.2206A>C p.I736L | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV51372581; called by muse, mutect2, varscan2
- DAAM2 | c.2871C>A p.F957L (on ENST00000274867 / NM_001201427.2; = p.F956L on NM_015345.3) | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV51303384; called by muse, mutect2, varscan2
- DAB1 | c.941C>T p.A314V (on ENST00000371231; = p.A281V on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs768523539, COSV64699548; called by muse, mutect2, varscan2
- DAPK1 | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs748494486, COSV63783719; called by muse, varscan2
- DARS1 | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99927826; called by muse, mutect2, varscan2
- DBH | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 87/586 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs202213535, COSV55040156; called by muse, mutect2, varscan2
- DBR1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.829); catalogued as rs139875059; called by muse, mutect2, varscan2
- DCAF1 | c.3498G>T p.M1166I | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.679); catalogued as rs1375919988; called by muse, mutect2, varscan2
- DCAF10 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV104386667, COSV54289880; called by muse, mutect2, varscan2
- DCAF4L1 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.238); catalogued as rs1336546037, COSV60786440; called by muse, mutect2, varscan2
- DCAF4L2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs1202467100, COSV100151058, COSV60479030; called by muse, mutect2, varscan2
- DCAF8L1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs767977769, COSV71595101; called by muse, mutect2, varscan2
- DCAF8L2 | c.1400G>T p.R467I | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70550263; called by muse, mutect2, varscan2
- DCBLD2 | c.1077G>T p.K359N | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769625584, COSV58793594; called by muse, mutect2
- DCC | c.2192C>A p.S731Y | Missense Mutation (SNP) | VAF 48/297 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100501200, COSV59143639; called by muse, varscan2
- DCC | c.3101C>T p.S1034F | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV100502243; called by muse, mutect2, varscan2
- DCLK1 | c.2149G>A p.E717K (on ENST00000360631 / NM_001330072.2; = p.E410K on NM_001195416.2) | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.055); catalogued as COSV55174416; called by muse, varscan2
- DCLK1 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.882); catalogued as rs575565299, COSV55177808; called by muse, mutect2, varscan2
- DCLK2 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1362496562; called by muse, mutect2, varscan2
- DCLK2 | c.1543G>T p.D515Y | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56208210; called by muse, varscan2
- DCN | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV50006179, COSV50008176; called by muse, mutect2
- DCUN1D1 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 31/194 reads (16%) | catalogued as COSV53044238; called by muse, varscan2
- DDR2 | c.1774G>T p.D592Y | Missense Mutation (SNP) | VAF 59/407 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV63371893; called by muse, varscan2
- DDX17 | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99318857; called by muse, mutect2, varscan2
- DDX27 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV65609472; called by muse, mutect2, varscan2
- DDX4 | c.1880G>A p.R627Q | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61755946; called by muse, mutect2, varscan2
- DDX53 | c.1418T>C p.F473S | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1468360907; called by muse, mutect2, varscan2
- DEF8 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs745450441; called by muse, mutect2, varscan2
- DEFB116 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 59/368 reads (16%) | catalogued as COSV101269248, COSV68722154; called by muse, mutect2, varscan2
- DENND11 | c.510C>A p.F170L | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV72097624; called by muse, mutect2
- DENND1C | c.1666G>T p.E556* | Nonsense Mutation (SNP) | VAF 53/362 reads (15%) | catalogued as rs768841845; called by muse, mutect2, varscan2
- DENND3 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52800541; called by muse, mutect2, varscan2
- DENND3 | c.3190G>T p.E1064* | Nonsense Mutation (SNP) | VAF 20/131 reads (15%) | catalogued as COSV52801105; called by muse, mutect2, varscan2
- DENND4A | c.3196A>C p.I1066L | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV71266725; called by muse, mutect2, varscan2
- DENND4A | c.2491C>T p.R831* | Nonsense Mutation (SNP) | VAF 31/239 reads (13%) | catalogued as rs780450925, COSV71265577; called by muse, mutect2, varscan2
- DENND5B | c.3082C>T p.R1028W | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100171171; called by muse, mutect2, varscan2
- DENND5B | c.2063G>A p.R688H | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs369424650; called by muse, mutect2, varscan2
- DESI2 | c.304C>A p.H102N | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55643442; called by muse, varscan2
- DGCR2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1431803370, COSV54220216; called by muse, mutect2, varscan2
- DGKD | c.1165G>A p.E389K (on ENST00000264057 / NM_152879.3; = p.E345K on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/296 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1489569831, COSV51037406; called by muse, mutect2, varscan2
- DGUOK | c.463C>A p.L155I | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV51203297; called by muse, mutect2, varscan2
- DHX15 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV61026232; called by muse, mutect2, varscan2
- DHX33 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 42/190 reads (22%) | catalogued as rs912647943; called by muse, mutect2, varscan2
- DIAPH2 | c.218T>G p.L73R | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.658); catalogued as rs1246686709, COSV61264681; called by muse, mutect2, varscan2
- DIAPH2 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as COSV61260792; called by muse, mutect2, varscan2
- DIAPH2 | c.1579G>T p.E527* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as COSV100236169, COSV61268693; called by muse, mutect2, varscan2
- DIAPH3 | c.1343G>A p.R448Q (on ENST00000400324 / NM_001042517.2; = p.R185Q on NM_030932.3) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs145827856, COSV57369405; called by muse, mutect2, varscan2
- DIS3 | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV58328672; called by muse, mutect2, varscan2
- DIS3L2 | c.1041C>A p.F347L | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56049096; called by muse, mutect2, varscan2
- DISC1 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 59/400 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs367543096; ClinVar: not provided; called by muse, mutect2, varscan2
- DISP1 | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs752790327, COSV52662040, COSV99451619; called by muse, mutect2, varscan2
- DISP1 | c.2517C>A p.F839L | Missense Mutation (SNP) | VAF 102/685 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52660969, COSV99450642; called by muse, mutect2, varscan2
- DKK4 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 50/397 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766494052, COSV55184343; called by muse, mutect2, varscan2
- DLC1 | c.2698G>A p.E900K (on ENST00000276297 / NM_001348081.2; = p.E463K on NM_006094.5) | Missense Mutation (SNP) | VAF 52/331 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as rs772280518, COSV52310754; called by muse, mutect2, varscan2
- DLG1 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 33/153 reads (22%) | catalogued as rs1295215276; called by muse, mutect2, varscan2
- DLG3 | c.1711G>T p.E571* (on ENST00000374360 / NM_021120.4; = p.E234* on NM_020730.3) | Nonsense Mutation (SNP) | VAF 48/294 reads (16%) | catalogued as COSV99529843; called by muse, mutect2, varscan2
- DMBT1 | c.7610G>A p.R2537Q (on ENST00000338354 / NM_001377530.1; = p.R1780Q on NM_004406.3) | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs771169614, COSV57535268; called by muse, mutect2, varscan2
- DMD | c.10396G>T p.D3466Y | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58891071; called by muse, varscan2
- DMD | c.8450T>G p.L2817R | Missense Mutation (SNP) | VAF 95/520 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58914465; called by muse, mutect2, varscan2
- DMD | c.7667G>T p.R2556I | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV58889726, COSV58946219; called by muse, mutect2, varscan2
- DMD | c.5476G>T p.E1826* | Nonsense Mutation (SNP) | VAF 40/252 reads (16%) | catalogued as CM096756, COSV63782395; called by muse, mutect2, varscan2
- DMD | c.5309G>T p.R1770I | Missense Mutation (SNP) | VAF 67/384 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV63742543; called by muse, mutect2, varscan2
- DMD | c.4701G>T p.E1567D | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100817124; called by muse, mutect2, varscan2
- DMGDH | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 56/302 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778394636, COSV54867234, COSV99668797; called by muse, mutect2, varscan2
- DMRT2 | c.1570G>T p.D524Y | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs781594613, COSV52401916; called by muse, mutect2, varscan2
- DMXL1 | c.7901G>T p.R2634I | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs761825409; called by mutect2, varscan2
- DMXL2 | c.7346T>G p.F2449C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51846626; called by muse, mutect2, varscan2
- DNAAF2 | c.1651G>T p.D551Y | Missense Mutation (SNP) | VAF 100/609 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs1312895297; called by muse, mutect2, varscan2
- DNAH10 | c.5897G>A p.R1966Q (on ENST00000409039; = p.R1905Q on NM_207437.3) | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.066); catalogued as rs759186375, COSV68991934; called by muse, mutect2, varscan2
- DNAH10 | c.10648G>A p.D3550N (on ENST00000409039; = p.D3489N on NM_207437.3) | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68988348; called by muse, mutect2, varscan2
- DNAH11 | c.2053C>T p.R685C | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs754405810, COSV60971443; called by muse, mutect2, varscan2
- DNAH12 | c.9163C>A p.L3055I (on ENST00000351747; = p.L3923I on NM_001366028.2) | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61063682; called by muse, mutect2
- DNAH12 | c.6071G>A p.R2024Q (on ENST00000351747; = p.R2043Q on NM_001366028.2) | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs917199476, COSV61058025; called by muse, mutect2, varscan2
- DNAH12 | c.188G>T p.R63I | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV60857036; called by muse, mutect2, varscan2
- DNAH17 | c.5770C>T p.R1924W | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768967388, COSV67752677; called by muse, mutect2, varscan2
- DNAH2 | c.3429G>T p.E1143D | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV101209167; called by muse, mutect2, varscan2
- DNAH2 | c.6025G>A p.D2009N | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773865335; called by muse, mutect2, varscan2
- DNAH2 | c.6737C>A p.P2246Q | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV66717413; called by muse, mutect2, varscan2
- DNAH2 | c.6894G>T p.E2298D | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV66725527; called by muse, mutect2, varscan2
- DNAH3 | c.9415G>A p.E3139K | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747847157, COSV54516589; called by muse, mutect2, varscan2
- DNAH3 | c.8904G>T p.E2968D | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104372710; called by muse, mutect2, varscan2
- DNAH5 | c.10180G>A p.E3394K | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs770289921, COSV54204170; called by muse, mutect2, varscan2
- DNAH5 | c.9214G>A p.D3072N | Missense Mutation (SNP) | VAF 82/404 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs749838880; called by muse, mutect2, varscan2
- DNAH5 | c.7288G>A p.E2430K | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs575491117; called by muse, mutect2, varscan2
- DNAH6 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 37/116 reads (32%) | catalogued as rs1183655863, COSV52853764; called by muse, mutect2, varscan2
- DNAH6 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 17/109 reads (16%) | catalogued as rs1351299060, COSV52853769; called by muse, mutect2
- DNAH6 | c.5791C>A p.L1931I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV52863879; called by muse, mutect2
- DNAH6 | c.9080C>T p.S3027F | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs748322842; called by muse, mutect2, varscan2
- DNAH7 | c.11848C>A p.L3950I | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV104395610; called by muse, mutect2, varscan2
- DNAH7 | c.9121G>A p.E3041K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753140811, COSV56774194; called by muse, mutect2, varscan2
- DNAH7 | c.8227C>A p.L2743I | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56770065; called by muse, mutect2, varscan2
- DNAH7 | c.2692G>T p.E898* | Nonsense Mutation (SNP) | VAF 46/271 reads (17%) | catalogued as rs376917562, COSV56765219; called by muse, mutect2, varscan2
- DNAH7 | c.2299C>A p.L767I | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.849); catalogued as COSV100415697; called by muse, mutect2, varscan2
- DNAH7 | c.1881G>T p.Q627H | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV56751248; called by muse, mutect2, varscan2
- DNAH8 | c.1743C>T p.Y581= | Splice Region (SNP) | VAF 18/126 reads (14%) | catalogued as rs762160890; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV59464779; called by muse, mutect2, varscan2
- DNAH8 | c.8429G>A p.R2810Q | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs771436783, COSV59443639; called by muse, mutect2, varscan2
- DNAH8 | c.11260G>A p.E3754K | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs267601020, COSV59439459; called by muse, mutect2, varscan2
- DNAH9 | c.2032C>A p.L678I | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52368777; called by muse, mutect2, varscan2
- DNAH9 | c.2533C>T p.R845* | Nonsense Mutation (SNP) | VAF 35/195 reads (18%) | catalogued as rs980814340; called by muse, mutect2, varscan2
6,582 further variants in this file (4,611 protein-altering or splice-affecting, 1,078 silent, 893 other) are not listed here.
